Gene-level copy-number profile of tumor specimen ALCH-B01Q-TTP1-A from ALCHEMIST case ALCH-B01Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 70.4 years (25,701 days).
Specimen ALCH-B01Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5b8bb14e-b49a-42f0-82b0-465e5d307ffc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B01Q-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,776 have no estimate.
https://portal.gdc.cancer.gov/files/374a5823-1dd9-4812-ae2a-dcf29d0d86cd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 638; copy number 1: 8,311; copy number 2: 25,976; copy number 3: 16,025; copy number 4: 5,584; copy number 5: 1,881; copy number 6: 201; copy number 7: 17; copy number 8: 138; copy number 9: 1; copy number 15: 28; copy number 16: 3; copy number 50: 18; copy number 53: 26.

Homozygous deletions (total copy number 0; autosomes only): 165 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,851,791–91,580,863, 42 genes: IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2.
- chr2:91,759,462–91,843,802, 4 genes: AC027612.3, GGT8P, IGKV1OR2-1, ABCD1P5.
- chr3:31,452,832–31,455,894, 1 gene: THRAP3P1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr4:187,970,273–188,161,157, 8 genes: AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434.
- chr5:70,925,030–71,133,287, 7 genes: SMN1, AC139834.1, NAIP, GTF2H2, OCLNP1, NAIPP4, CDH12P4.
- chr6:89,059,628–89,063,690, 2 genes: AL079342.2, RNU2-61P.
- chr8:28,600,469–28,755,599, 2 genes: EXTL3, EXTL3-AS1.
- chr9:22,767,175–22,768,316, 1 gene (within-gene range 0–1): AC017067.1.
- chr9:36,336,396–36,487,548, 1 gene: RNF38.
- chr10:91,765,899–91,798,304, 2 genes: FAF2P1, TNKS2-AS1.
- chr10:124,748,149–124,791,887, 1 gene (within-gene range 0–1): EEF1AKMT2.
- chr10:124,801,819–124,868,326, 3 genes: ABRAXAS2, Y_RNA, NPM1P31.
- chr11:4,278,705–4,279,192, 1 gene: SSU72P6.
- chr12:37,575,587–42,144,874, 50 genes: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC023513.1, GXYLT1.
- chr13:20,973,036–21,061,586, 3 genes (within-gene range 0–1): LATS2, LATS2-AS1, RNU4-9P.
- chr14:18,333,726–18,412,264, 3 genes: CR383658.1, RNU6-458P, CR383658.2.
- chr15:78,810,487–78,898,139, 3 genes (within-gene range 0–2): MORF4L1, AC103975.1, RPL21P116.
- chr16:35,836,886–35,837,732, 1 gene: VN1R70P.
- chr17:81,637,171–81,648,749, 1 gene (within-gene range 0–3): TSPAN10.
- chr17:82,359,247–82,382,690, 4 genes: TEX19, AC132938.4, UTS2R, AC132938.1.
- chr17:82,729,164–82,734,143, 1 gene (within-gene range 0–3): AC024361.3.
- chr19:5,782,960–5,791,225, 3 genes: PRR22, AC011499.1, DUS3L.
- chr19:42,839,368–42,855,718, 1 gene (within-gene range 0–1): PSG10P.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:24,181,487–24,189,106, 1 gene: SUSD2.
- chr22:38,656,636–38,685,421, 5 genes: CBY1, AL021707.4, AL021707.2, AL021707.9, TOMM22.
- chr22:43,038,585–43,187,134, 7 genes: TTLL1-AS1, TTLL1, AL022237.1, BIK, MCAT, TSPO, TTLL12.
- chr22:43,212,674–43,213,661, 1 gene (within-gene range 0–1): SCUBE1-AS2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,285 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,399,520–1,410,618, 4 genes, copy number 6: MRPL20-AS1, MRPL20, RN7SL657P, MRPL20-DT.
- chr4:120,639,090–129,305,022, 95 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 5–6 (broad region; genes not listed).
- chr6:33,437,363–33,454,453, 1 gene, copy number 6 (within-gene range 4–6): SYNGAP1-AS1.
- chr6:33,453,970–33,457,544, 1 gene, copy number 6 (within-gene range 4–6): ZBTB9.
- chr7:7,066,964–7,079,742, 2 genes, copy number 8: MIR3683, AC092104.1.
- chr7:62,275,361–62,275,678, 1 gene, copy number 6: AC128676.1.
- chr7:74,650,231–74,789,376, 4 genes, copy number 6: GTF2I, AC211433.1, PHBP15, NCF1.
- chr8:7,256,904–7,298,024, 3 genes, copy number 9–16: FAM90A15P, FAM90A3P, FAM90A20P.
- chr8:124,811,042–125,541,373, 17 genes, copy number 50: AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1.
- chr8:125,749,055–125,750,241, 1 gene, copy number 50: AC016074.1.
- chr8:127,289,817–129,683,770, 26 genes, copy number 53 (within-gene range 3–53): CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr8:143,246,821–143,384,221, 10 genes, copy number 6: ZFP41, AC138696.1, GLI4, MINCR, ZNF696, AC138696.2, TOP1MT, RNU6-220P, RHPN1-AS1, RHPN1.
- chr8:143,632,071–143,790,645, 12 genes, copy number 7 (within-gene range 4–7): AC067930.2, ZNF623, ZNF707, LINC02878, CCDC166, AC105219.2, MAPK15, AC105219.1, FAM83H, MIR4664, IQANK1, AC105219.3.
- chr9:30,935,485–31,645,160, 8 genes, copy number 6: FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr9:33,524,394–36,304,924, 147 genes, copy number 6–8 (broad region; genes not listed).
- chr9:36,572,862–36,677,683, 1 gene, copy number 5: MELK.
- chr9:120,600,811–120,714,470, 1 gene, copy number 5: MEGF9.
- chr11:48,880,111–48,908,946, 4 genes, copy number 7: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr12:4,269,771–10,523,135, 279 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr12:102,012,840–102,074,820, 2 genes, copy number 6 (within-gene range 3–6): WASHC3, AC079907.1.
- chr15:21,405,401–21,946,641, 28 genes, copy number 15: POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.
- chr18:45,034–5,630,700, 117 genes, copy number 5 (broad region; genes not listed).
- chr18:14,377,546–14,430,923, 3 genes, copy number 5: TERF1P2, FEM1AP2, AP006261.1.
- chr18:14,477,955–14,499,278, 2 genes, copy number 6: CXADRP3, GRAMD4P7.
- chr18:20,946,906–80,247,514, 832 genes, copy number 5–8 (broad region; genes not listed).
- chr19:42,226,225–42,255,132, 4 genes, copy number 5 (within-gene range 4–5): GSK3A, AC006486.1, AC006486.2, ERF.
- chr21:43,053,191–43,076,943, 1 gene, copy number 16: CBS.

Autosomal genes at a single copy (total copy number 1): 7,156. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
